Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TD-01A (Primary Tumor).

[page 1 of 4]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Pathology Report:

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site C6CF
Anterior wall of bladder
path C67.3
Overlapping lesion of
bladder C67.8
9/27/22/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph nodes; dissection:

- Thirteen lymph nodes, no tumor (0/13).

B. Left pelvic lymph nodes; dissection:

- Twenty-one lymph nodes, no tumor (0/21).

C. Urinary bladder and prostate; cystoprostatectomy:

- Bladder with invasive urothelial carcinoma invading thru the muscularis propria and into the perivesical tissue, see pathologic parameters.

- Prostate with prostatic adenocarcinoma, see pathologic parameters.

- Resection margins, free of tumor.

D. Left distal ureter; excision:

- Portion of ureter, no tumor.

E. Right distal ureter; excision:

- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (microscopic).
4. Tumor distribution: Solitary, 7.5 cm, located at right lateral wall, anterior wall and posterior bladder wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/34).
9. pTNM: pT3a,N0,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging

[page 2 of 4]
system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+4=7, see comment.
2. Perineural Invasion: Absent.
3. Tumor Location: Peripheral zone - right and left; Transition zone - right.
4. Tumor Volume Estimate: 30%.
5. High-grade P.I.N.: Multifocal.
6. Seminal Vesicles: Negative for tumor.
7. Extraprostatic extension: Present (left side).
8. Peripheral Margin: Negative for tumor.
9. Distal (apical) Margin: Negative for tumor.
10. Proximal (basilar) Margin: Negative for tumor
11. Regional Lymph Nodes (right and left): Negative for tumor (0/34).
12. pTNM: pT3a,N0,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

The prostatic adenocarcinoma exhibits some degree of tumor cell shrinkage, possibly from prior hormonal therapy. Please correlate clinically.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] MD, PhD
Electronically Signed Out by [], MD

Clinical History:

Patient is a year-old male with bladder cancer who undergoes cystectomy with ileo-conduit.

Specimens Received:

- A: Right pelvic lymph nodes
- B: Left pelvic lymph nodes
- C: Prostate and bladder
- D: Left distal ureter - suture on non-margin side
- E: Right distal ureter - suture on non-margin side

Gross Description:

[page 3 of 4]
The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "1. Right pelvic lymph nodes". Received fresh and placed in formalin is a 10 x 7.2 x 2 cm portion of soft lobulated yellow-tan adipose tissue. The specimen is searched for lymph nodes, and 16 candidates are identified ranging in size from 0.5 cm up to 3.5 cm in greatest dimension. All the lymph nodes are submitted as follows:

A1: 5 lymph nodes

A2: 4 lymph nodes

A3: 2 nodes

A4-5: 1 node bisected

A6-7: 1 node bisected

B. The second container is additionally identified as, "2. Left pelvic lymph nodes". Received fresh and placed in formalin is a 10 x 8.5 x 2.5 cm aggregate of soft yellow-tan fibroadipose tissue. The specimen is searched for lymph nodes, and 26 candidates are identified ranging in size from 0.6 cm up to 2.6 cm in greatest dimension. All of the lymph nodes are submitted as follows:

B1-3: 6 nodes in each cassette

B4: 4 nodes

B5: 2 nodes

B6-7: 1 node bisected in each cassette

C. The third container is additionally identified as, "3. Bladder and prostate". Received fresh and placed in formalin is a 554.8 g, 19.0 x 12.0 x 5.0 cm cystoprostatectomy specimen consisting of a 9.5 x 7.5 x 4.0 cm bladder with attached mesenteric fat and a 5.5 x 4.0 x 3.8 cm prostate. The right seminal vesicles measure 4.5 x 2.2 x 0.6 cm and right vas deferens measures 7.5 x 0.3 cm. The left seminal vesicles measures 4.5 x 1.8 x 0.7 cm and left vas deferens measures 8.0 x 0.3 cm. The right ureteral stump measures 3.0 x 0.7 cm, the left measures 2.5 x 0.5 cm, and both demonstrate intact, patent lumens. Two detached segments of vas measuring 7.5 x 0.3 cm and 8.0 x 0.3 cm are found separately in the same container as the main specimen.

The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with 0.9 x 0.6 x 0.6 cm discrete indurations in the left lateral half. The prostatic apex is disrupted along the posterior aspect. Approximately 50% of the prostate is submitted.

The opened bladder reveals a 7.5 x 5.5 cm indurated, hemorrhagic, edematous, shaggy, mucosa with central ulceration measuring 4.5 x 4.0 cm located in the

[page 4 of 4]
posterior wall, right lateral wall and right anterior wall. On cut section, the mass extends through the muscularis propria, and is 0.2 cm from the deep margin. The greatest dimension of tumor extension to the margin is approximately 2.6 cm. The urethral orifices and trigone are spared. The surrounding bladder mucosa is edematous, wrinkled, congested, pink-tan with a uniform 0.8 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent. Gross photographs are taken.

Representative sections are submitted as follows:

- C1: Left ureter resection margin
- C2: Right ureter resection margin
- C3: Urethral margin
- C4-C6: Distal prostatic (apex)
- C7-C8: Bladder mass/Ulceration, greatest invasion, tandem sections
- C9-C10: Bladder mass/Ulceration, greatest invasion, tandem sections
- C11-C13: Bladder mass/Ulceration,
- C14: Uninvolved bladder mucosa bladder dome
- C15: Uninvolved bladder mucosa anterior wall
- C16: Uninvolved bladder mucosa posterior wall
- C17: Additional section of Bladder mass/Ulceration,
- C18-C25: Representative right lobe of prostate from apex to base
- C26 C33: Representative left lobe of prostate submitted from apex to base
- C34: Right bladder wall
- C35: Left bladder wall
- C36: Right vas deferens and seminal vesicle
- C37: Left vas deferens and seminal vesicle

D. The fourth container is additionally identified as, "4. Left distal ureter, suture on non-margin side". Received fresh and placed in formalin is a 1.7 cm in length by 0.6 cm in external diameter pink-tan portion of tubular tissue with a lumen consistent with ureter. One aspect is stitch indicating the non-margin side.. The non-margin side is inked in black, and the true margin side is inked in blue. Each side is shaved and submitted en face in D1.

E. The fifth container is additionally identified as, "5. Right distal ureter, suture on non-margin side".

Received fresh and placed in formalin is a 2.5 cm in length by 0.9 cm external diameter pink-tan tubular structure with a lumen consistent with ureter. One aspect has a stitch indicating the non-margin side. This aspect is inked in black, and the true margin side is inked in blue. Each margin is shaved and submitted en face and E1.

Dual/Synchronous Primary	Prostate ✓	

Source: NCI Genomic Data Commons file 18f5b883-3dec-484d-9001-429a9e5f1cbe (TCGA-FD-A6TD.11A1BF15-67A7-4D7F-B4F2-67EE00685E82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).